CCDI case PBBIEN — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS; Primary site: Brain.
https://portal.gdc.cancer.gov/cases/4a118f27-d581-4095-bd68-a6effc056735

Demographics
Sex at birth: female; Race: white.

Diagnoses (1)
1. Medulloblastoma, NOS: ICD-O-3 morphology code: 9470/3; Tissue or organ of origin: Brain stem; Age at diagnosis: 8.8 years (3,215 days).

Biospecimens (3 samples)
- Sample 0D920K: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0D921C: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Sample 0D94VE: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
